Somatic mutation profile of tumor specimen 0DLZOK from CCDI case PBBZVU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.3 years (4,128 days).
Specimen 0DLZOK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eec9ea79-dcd0-4853-a255-23e15dea27c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLZND (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8edf03b-e96f-4a77-bff0-ad586233d903

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLNC | c.3025C>T p.R1009W | Missense Mutation (SNP) | VAF 34/554 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs746542712; called by muse, mutect2
- PCDHGA8 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 40/940 reads (4%) | catalogued as rs1561643318; called by muse, mutect2
- SIRPD | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 191/530 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs753467977, COSV67547154; called by muse, mutect2, varscan2
- DNMT3A | c.1527_1530del p.F509Lfs*141 | Frame Shift Del (DEL) | VAF 240/652 reads (37%) | called by mutect2, pindel, varscan2
- KIAA0930 | c.1156C>G p.L386V (on ENST00000336156 / NM_001009880.2; = p.L391V on NM_015264.2) | Missense Mutation (SNP) | VAF 34/645 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.061); called by muse, mutect2
- TERB1 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 147/466 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
